FM case AD9936 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/abd4588d-954e-44a3-a4ab-366d728c1f5e

Male, 78.1 years: diagnosis not reported by GDC; metastasis biopsied or resected from the nasal cavity. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
